Somatic mutation profile of tumor specimen TCGA-78-7160-01A (aliquot TCGA-78-7160-01A-11D-2036-08) from TCGA case TCGA-78-7160, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 61.3 years (22,385 days).
Specimen TCGA-78-7160-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0400c27-d826-4c7f-8993-15d8f84d58d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7160-10A (Blood Derived Normal), aliquot TCGA-78-7160-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc39b9bf-3853-4d10-87e1-d7f7c8fe4cf3

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 21, Silent 15, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3320T>C p.V1107A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV60685039; called by muse, mutect2, varscan2
- ABCG2 | c.1368-2A>T p.X456_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV52945642; called by muse, mutect2, varscan2
- CBY2 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); catalogued as rs1163987761, COSV60118129; called by muse, mutect2, varscan2
- CLCN5 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV56583687; called by muse, mutect2, varscan2
- DLEC1 | c.874-2A>G p.X292_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV57299057; called by muse, mutect2, varscan2
- FAM120C | c.2893G>T p.V965L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60259090; called by muse, mutect2, varscan2
- GMEB2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV56606958; called by muse, mutect2
- HOXC11 | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54533094; called by muse, mutect2, varscan2
- KCNA2 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.044); catalogued as rs1243365734, COSV60369782; called by muse, mutect2, varscan2
- L1CAM | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.113); catalogued as COSV62827981; called by muse, mutect2, varscan2
- LILRB4 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs777785831, COSV54403281; called by muse, mutect2
- LRRC6 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1181804238, COSV51541182; called by muse, mutect2, varscan2
- LRRC7 | c.1298C>A p.A433D (on ENST00000651989 / NM_001370785.2; = p.A400D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV50431534, COSV50449375; called by muse, mutect2, varscan2
- PARD3B | c.3180+1G>T p.X1060_splice (on ENST00000406610 / NM_001302769.2; = p.X991_splice on NM_057177.7) | Splice Site (SNP) | VAF 18/112 reads (16%) | catalogued as COSV62510063; called by muse, mutect2, varscan2
- PHLDB2 | c.3202G>A p.E1068K (on ENST00000393925 / NM_001134439.2; = p.E1025K on NM_145753.2) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67310731; called by muse, mutect2, varscan2
- PLEC | c.2135C>T p.A712V (on ENST00000322810 / NM_201380.4; = p.A602V on NM_000445.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59631789; called by muse, mutect2, varscan2
- PRKRA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1293335092, COSV57868620; called by muse, mutect2
- RC3H2 | c.3361G>C p.G1121R | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as rs1219872901, COSV61799779; called by muse, mutect2, varscan2
- RINT1 | c.1640C>G p.S547* | Nonsense Mutation (SNP) | VAF 4/78 reads (5%) | catalogued as COSV57558358; called by muse, mutect2
- SUV39H2 | c.584A>G p.D195G (on ENST00000354919 / NM_001193424.2; = p.D135G on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57953758; called by muse, mutect2, varscan2
- TRMT2A | c.794A>T p.Y265F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52813273; called by muse, varscan2
- UGT1A10 | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV60837703; called by muse, mutect2, varscan2
- ZNF571 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV60733023; called by muse, mutect2, varscan2
- ZNF711 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52153663; called by muse, mutect2, varscan2
- KEAP1 | c.839_863del p.F280Sfs*29 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel
- MYO19 | c.2050G>T p.D684Y (on ENST00000614623 / NM_001163735.1; = p.D484Y on NM_025109.5) | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- RIPPLY3 | c.340_350del p.D114* | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- ABCC6 | c.4173G>A p.L1391= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52743526; called by muse, mutect2, varscan2
- ADCY6 | c.2718G>T p.A906= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV100326581, COSV57167652; called by muse, mutect2
- BTN1A1 | c.1260C>A p.R420= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV55067126; called by muse, mutect2, varscan2
- CCDC180 | c.2454A>G p.E818= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV63829709; called by muse, mutect2, varscan2
- FCRL5 | c.2391G>A p.S797= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs760916744, COSV62513993; called by muse, mutect2, varscan2
- GPRASP2 | c.918C>T p.P306= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV59991109; called by muse, mutect2, varscan2
- KRTAP13-4 | c.96C>T p.S32= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV61879126; called by muse, mutect2, varscan2
- LINGO2 | c.1452C>A p.I484= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs150860330, COSV58058320; called by mutect2, varscan2
- MYH4 | c.699C>T p.F233= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs780206832, COSV55117392; called by muse, mutect2, varscan2
- PCLO | c.2070A>G p.P690= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV61632213; called by muse, mutect2, varscan2
- PTOV1 | c.657C>G p.P219= | Silent (SNP) | VAF 31/247 reads (13%) | catalogued as COSV55587616; called by muse, mutect2, varscan2
- RALGPS2 | c.441A>G p.L147= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs1268284430, COSV61336897; called by muse, mutect2, varscan2
- TRPV5 | c.789G>A p.R263= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs765786514, COSV54684335; called by muse, mutect2, varscan2
- UGT2B15 | c.1143C>A p.I381= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV57733514, COSV57734277; called by muse, mutect2
- ZNF208 | c.75G>A p.Q25= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as COSV68104525; called by muse, mutect2
